Surgical pathology report (de-identified scan), TCGA case TCGA-HU-A4GD, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site National Cancer Center Korea, specimen TCGA-HU-A4GD-01A (Primary Tumor).

[page 1 of 3]
Subject ID

GROSS:

Specimen state: Fresh

Procedure: Distal gastrectomy

Organ: Stomach

Greater curvature 19.0 cm

Lesser curvature 9.8 cm

Proximal resection 14.0 cm

Distal resection margin 5.7 cm

Duodenum 1.7 cm

Lesion: Ulcerofungating mass

Size: 4.5 x 4.0 cm

Tumor type: Borrmann type II

Safety margin - Proximal: 2.0 cm

- Distal: 3.0 cm

Gross serosal invasion: No

Representative sections submitted

Gross photo: Present

Blocks

T1-4 and TB, tumor and surrounding tissue x 5

A an NB, antrum x 2

B, body mucosa x 1

P, proximal resection margin x 1

DRM, distal resection margin x 1

LN1-3, superior gastric lymph nodes x 3

LN4-5, inferior gastric lymph nodes x 2

LN6, '1' lymph nodes x 1

LN7, '4sb' lymph nodes x 1

LN8, '5' lymph nodes x 1

LN9, '6' lymph nodes x 1

LN10, '7' lymph nodes x 1

LN11, '8' lymph nodes x 1

LN12, '9' lymph nodes x 1

LN13-14, '11p' lymph nodes x 2

LN15, '12' lymph nodes x 1

MICROSCOPIC:

ICD-0-3

adenocarcinoma, tubular 8211/3

CQCF Site: Stomach, antrum C16.3

Path: Stomach, NOS C16.9

lw 9/27/12

[page 2 of 3]
Tumor type: Adenocarcinoma
Differentiation: Moderately differentiated
Depth of tumor invasion:
T3-subserosa
Margins: Proximal resection margin (-)
Distal resection margin (-)
Lauren classification: Intestinal
Ming classification (Growth pattern): Infiltrative
Lymphoid reaction: Present
Lymphovascular invasion: Present, multiple
Venous (large vessel) invasion: Present
Perineural invasion: Absent
Lymph node metastasis: Present (2/40)
Pathologic stage: pT3N1Mx (AJCC 7th edition)

DIAGNOSIS:

Stomach, distal gastrectomy:
Adenocarcinoma, moderately differentiated, infiltrating
(advanced gastric cancer)

<Addendum>

Final diagnosis: Stomach Intestinal Adenocarcinoma, Tubular Type

Lymph node, perigastric, distal gastrectomy:
Superior gastric: Metastatic carcinoma, primary in stomach (1/7)
Inferior gastric: No tumor present (0/8)
Lymph node, regional, biopsy:
Labeled as '1': No tumor present (0/2)
Labeled as '4sb': No tumor present (0/1)
Labeled as '5': No tumor present (0/1)
Labeled as '6': No tumor present (0/4)
Labeled as '7': No lymphoid tissue
Labeled as '8': No tumor present (0/5)
Labeled as '9': No tumor present (0/4)
Labeled as '11p': Metastatic carcinoma, primary in stomach (1/7)
Labeled as '12': No tumor present (0/1)

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): Stomach adenocarcinoma

Completed By _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Stomach Intestinal Adenocarcinoma	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF	Stomach Intestinal Adenocarcinoma, Tubular Type	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Original pathologic diagnosis was adenocarcinoma, moderately - differentiated. Review of TCGA sample top slide confirmed this tumor as stomach Intestinal adenocarcinoma-tubular type and addedum was created as such	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 75f6bf77-54a6-4ca5-996b-49b0f1172d77 (TCGA-HU-A4GD.EE76925D-507D-40F9-A024-A64D89C6A448.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).